Somatic mutation profile of tumor specimen TCGA-CG-5724-01A (aliquot TCGA-CG-5724-01A-11D-1600-08) from TCGA case TCGA-CG-5724, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Carcinoma, diffuse type; Tissue or organ of origin: Gastric antrum; AJCC pathologic stage: Stage IV; Tumor grade: G3; Age at diagnosis: 59.6 years (21,762 days).
Specimen TCGA-CG-5724-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ee2ce6d1-efe9-48cf-8bc4-79425d298bb5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CG-5724-11A (Solid Tissue Normal), aliquot TCGA-CG-5724-11A-01D-1600-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/38eff58b-900d-4bbd-8142-024728720aed

The open-access MAF lists 113 somatic variants for this specimen: 83 protein-altering or splice-affecting, 29 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 72, Silent 29, Nonsense Mutation 3, Frame Shift Del 3, Frame Shift Ins 2, Splice Site 1, In Frame Del 1, RNA 1, Nonstop Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BCOR | c.2428C>T p.R810* | Nonsense Mutation (SNP) | VAF 85/128 reads (66%) | catalogued as rs1555918056, CM095797, COSV60703357; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ADAMTS12 | c.4160G>A p.R1387H | Missense Mutation (SNP) | VAF 69/200 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs745489312, COSV61254566, COSV61256573, COSV61285243; called by muse, mutect2, varscan2
- ADCY2 | c.1067A>G p.K356R | Missense Mutation (SNP) | VAF 64/340 reads (19%) | SIFT tolerated (0.93); PolyPhen benign (0.009); catalogued as COSV57857206, COSV57864358; called by muse, mutect2, varscan2
- ADD2 | c.7G>A p.E3K | Missense Mutation (SNP) | VAF 43/62 reads (69%) | SIFT tolerated (0.46); PolyPhen benign (0.083); catalogued as rs200519011, COSV52457097; called by muse, mutect2, varscan2
- ADGRV1 | c.9295G>A p.A3099T | Missense Mutation (SNP) | VAF 16/74 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.96); catalogued as COSV67981125; called by muse, mutect2, varscan2
- ALDOB | c.869G>T p.C290F | Missense Mutation (SNP) | VAF 10/154 reads (6%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.721); catalogued as rs1405680272, COSV66397550; called by muse, mutect2
- ARFGEF1 | c.2697G>T p.Q899H | Missense Mutation (SNP) | VAF 39/53 reads (74%) | SIFT tolerated (0.11); PolyPhen benign (0.013); catalogued as COSV51604888; called by muse, mutect2, varscan2
- ASPM | c.9860G>A p.C3287Y | Missense Mutation (SNP) | VAF 80/139 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54126938; called by muse, mutect2, varscan2
- BAZ2B | c.6374T>C p.F2125S | Missense Mutation (SNP) | VAF 42/76 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58597590; called by muse, mutect2, varscan2
- BNC2 | c.1087T>A p.Y363N | Missense Mutation (SNP) | VAF 78/116 reads (67%) | SIFT tolerated (0.25); PolyPhen benign (0.031); catalogued as COSV66143216; called by muse, mutect2, varscan2
- CALCRL | c.1321T>G p.L441V | Missense Mutation (SNP) | VAF 45/81 reads (56%) | SIFT tolerated (0.14); PolyPhen benign (0.219); catalogued as COSV66474110; called by muse, mutect2, varscan2
- CCDC178 | c.1274A>C p.K425T | Missense Mutation (SNP) | VAF 22/73 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.714); catalogued as COSV55765730; called by muse, mutect2, varscan2
- CCDC96 | c.1402G>A p.E468K | Missense Mutation (SNP) | VAF 176/414 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV59508376; called by muse, mutect2, varscan2
- CD2AP | c.961C>T p.P321S | Missense Mutation (SNP) | VAF 20/89 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63759325; called by muse, mutect2, varscan2
- CDH10 | c.302T>C p.L101P | Missense Mutation (SNP) | VAF 65/179 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV52574678; called by muse, mutect2, varscan2
- CDH11 | c.1070A>C p.K357T | Missense Mutation (SNP) | VAF 78/116 reads (67%) | SIFT deleterious (0.01); PolyPhen benign (0.158); catalogued as COSV51753026, COSV51757269, COSV99220171; called by muse, mutect2, varscan2
- CDK12 | c.2336G>A p.R779H | Missense Mutation (SNP) | VAF 13/76 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV70999863; called by mutect2, varscan2
- CLUH | c.824C>A p.P275H (on ENST00000435359; = p.P313H on NM_015229.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0.358); catalogued as COSV70928230; called by muse, mutect2, varscan2
- COL14A1 | c.1123C>A p.H375N | Missense Mutation (SNP) | VAF 17/64 reads (27%) | SIFT tolerated (0.09); PolyPhen benign (0.129); catalogued as COSV52850083; called by muse, mutect2, varscan2
- COL1A2 | c.3402A>C p.E1134D | Missense Mutation (SNP) | VAF 91/193 reads (47%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.978); catalogued as COSV51955221, COSV99800554; called by muse, mutect2, varscan2
- CSMD1 | c.2509T>G p.F837V (on ENST00000520002; = p.F836V on NM_033225.6) | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as COSV59299108, COSV59344712; called by muse, mutect2
- CSPG4 | c.4870C>T p.R1624W | Missense Mutation (SNP) | VAF 41/68 reads (60%) | SIFT deleterious (0); PolyPhen benign (0.328); catalogued as rs762365316, COSV57892632; called by muse, mutect2, varscan2
- DSCAM | c.4690G>A p.A1564T | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.854); catalogued as COSV68023461; called by muse, mutect2, varscan2
- EDNRB | c.508T>C p.S170P (on ENST00000377211 / NM_001201397.1; = p.S80P on NM_000115.5) | Missense Mutation (SNP) | VAF 22/118 reads (19%) | SIFT tolerated (0.25); PolyPhen benign (0.005); catalogued as COSV57520175; called by muse, mutect2, varscan2
- EXOC7 | c.1849C>T p.Q617* (on ENST00000335146 / NM_001145297.4; = p.Q535* on NM_015219.5 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 8/16 reads (50%) | catalogued as COSV58035384; called by mutect2, varscan2
- GART | c.3032G>T p.*1011Lext*33 | Nonstop Mutation (SNP) | VAF 22/67 reads (33%) | catalogued as COSV67818252; called by muse, mutect2, varscan2
- GFUS | c.640C>T p.R214W | Missense Mutation (SNP) | VAF 38/58 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as rs569059926, COSV55306357; called by muse, mutect2, varscan2
- HACL1 | c.1024C>T p.Q342* | Nonsense Mutation (SNP) | VAF 36/253 reads (14%) | catalogued as COSV58253923; called by muse, mutect2, varscan2
- HECTD4 | c.4184C>T p.A1395V | Missense Mutation (SNP) | VAF 4/72 reads (6%) | SIFT tolerated (0.42); PolyPhen benign (0.346); catalogued as COSV61178302; called by muse, mutect2
- HSDL2 | c.979A>G p.K327E | Missense Mutation (SNP) | VAF 89/180 reads (49%) | SIFT tolerated (0.06); PolyPhen benign (0.403); catalogued as COSV52714026; called by mutect2, varscan2
- IQCA1 | c.269T>A p.M90K | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); catalogued as COSV54498645; called by muse, mutect2, varscan2
- KLHL14 | c.1555C>T p.R519C | Missense Mutation (SNP) | VAF 59/111 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs757666427, COSV63831608; called by muse, mutect2, varscan2
- LARP4 | c.31A>G p.K11E | Missense Mutation (SNP) | VAF 55/122 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53321163; called by muse, mutect2, varscan2
- LGMN | c.868G>A p.A290T | Missense Mutation (SNP) | VAF 77/188 reads (41%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as rs1041810064, COSV58403086; called by muse, mutect2, varscan2
- LRP1B | c.4502A>C p.Q1501P | Missense Mutation (SNP) | VAF 98/177 reads (55%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.559); catalogued as COSV67199387; called by muse, mutect2, varscan2
- M1AP | c.236T>C p.F79S | Missense Mutation (SNP) | VAF 69/135 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1205005465, COSV51843485; called by muse, mutect2, varscan2
- MAGI3 | c.2770A>G p.K924E | Missense Mutation (SNP) | VAF 30/115 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV56831028; called by muse, mutect2, varscan2
- MAMDC2 | c.958A>G p.I320V | Missense Mutation (SNP) | VAF 199/276 reads (72%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.951); catalogued as COSV65857259; called by muse, mutect2, varscan2
- MDC1 | c.2573A>G p.D858G | Missense Mutation (SNP) | VAF 202/540 reads (37%) | SIFT tolerated (0.05); PolyPhen benign (0.023); catalogued as COSV64523859; called by muse, mutect2, varscan2
- MGAT4C | c.713A>C p.K238T | Missense Mutation (SNP) | VAF 56/119 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.903); catalogued as COSV59831183, COSV59831400; called by muse, mutect2, varscan2
- MGAT4C | c.29T>G p.I10S | Missense Mutation (SNP) | VAF 21/88 reads (24%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.003); catalogued as rs1306862350, COSV59831192; called by muse, mutect2, varscan2
- MLIP | c.382G>C p.E128Q | Missense Mutation (SNP) | VAF 46/176 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51427650; called by muse, mutect2, varscan2
- MUC16 | c.38972T>G p.L12991R | Missense Mutation (SNP) | VAF 33/55 reads (60%) | SIFT tolerated, low confidence (0.11); PolyPhen possibly damaging (0.455); catalogued as COSV67454090; called by muse, mutect2, varscan2
- NRDC | c.2921G>A p.C974Y | Missense Mutation (SNP) | VAF 227/383 reads (59%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.927); catalogued as COSV61402517; called by muse, mutect2, varscan2
- OR4C16 | c.89del p.L30Cfs*13 | Frame Shift Del (DEL) | VAF 98/240 reads (41%) | catalogued as rs752324980; called by mutect2, varscan2
- P2RY12 | c.187C>T p.L63F | Missense Mutation (SNP) | VAF 75/104 reads (72%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56373011; called by muse, mutect2, varscan2
- PCDHGA6 | c.1868C>T p.T623M | Missense Mutation (SNP) | VAF 24/95 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.957); catalogued as rs767101939, COSV53918069; called by muse, mutect2, varscan2
- PDAP1 | c.517C>G p.R173G | Missense Mutation (SNP) | VAF 53/204 reads (26%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0); catalogued as COSV53162876, COSV53163334; called by muse, mutect2, varscan2
- PFKFB2 | c.1093-2A>C p.X365_splice | Splice Site (SNP) | VAF 20/28 reads (71%) | catalogued as COSV65547510; called by muse, varscan2
- PKHD1 | c.8568A>C p.K2856N | Missense Mutation (SNP) | VAF 33/112 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.951); catalogued as COSV61866571; called by muse, mutect2, varscan2
- PRICKLE1 | c.1022G>A p.R341Q | Missense Mutation (SNP) | VAF 70/166 reads (42%) | SIFT tolerated (0.25); PolyPhen benign (0.012); catalogued as rs577174749, COSV61542462; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PRSS53 | c.108dup p.K37Qfs*44 | Frame Shift Ins (INS) | VAF 12/31 reads (39%) | catalogued as rs759089621; called by mutect2, varscan2
- PSKH1 | c.1028G>C p.R343P | Missense Mutation (SNP) | VAF 63/95 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52122432, COSV52122793; called by muse, mutect2, varscan2
- PTPRM | c.1918T>G p.L640V | Missense Mutation (SNP) | VAF 64/199 reads (32%) | SIFT tolerated (0.61); PolyPhen probably damaging (0.967); catalogued as COSV59850142; called by muse, mutect2, varscan2
- PUS7L | c.657T>A p.F219L | Missense Mutation (SNP) | VAF 36/179 reads (20%) | SIFT tolerated (0.12); PolyPhen benign (0.018); catalogued as rs780243371, COSV61261475; called by muse, mutect2, varscan2
- RPS6KC1 | c.2739G>A p.M913I | Missense Mutation (SNP) | VAF 120/192 reads (63%) | SIFT tolerated (0.29); PolyPhen benign (0.065); catalogued as COSV65298023; called by muse, mutect2, varscan2
- SBF2 | c.4919C>T p.T1640I | Missense Mutation (SNP) | VAF 40/67 reads (60%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.501); catalogued as COSV56294726; called by muse, mutect2, varscan2
- SEC14L1 | c.1003G>A p.D335N | Missense Mutation (SNP) | VAF 92/242 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66721380; called by muse, mutect2, varscan2
- SETDB1 | c.3722A>G p.D1241G | Missense Mutation (SNP) | VAF 27/82 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54979213; called by muse, mutect2, varscan2
- SH2D4A | c.512G>A p.R171Q | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs75590099, COSV56121882; called by muse, mutect2, varscan2
- SLC6A9 | c.1292G>A p.R431H (on ENST00000360584 / NM_201649.4; = p.R377H on NM_006934.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 41/99 reads (41%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.767); catalogued as rs200484133, COSV62210153; called by muse, mutect2, varscan2
- SLC7A6 | c.1018T>G p.S340A | Missense Mutation (SNP) | VAF 82/260 reads (32%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.812); catalogued as COSV54718231; called by muse, mutect2, varscan2
- SNX14 | c.1906G>A p.D636N (on ENST00000314673 / NM_001350535.1; = p.D583N on NM_020468.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 54/184 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV59010590; called by muse, mutect2, varscan2
- SOX7 | c.986G>A p.R329H | Missense Mutation (SNP) | VAF 17/67 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as rs370726272; called by muse, mutect2, varscan2
- TAAR2 | c.967C>T p.R323C (on ENST00000367931 / NM_001033080.1; = p.R278C on NM_014626.3) | Missense Mutation (SNP) | VAF 51/99 reads (52%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.947); catalogued as rs760868119, COSV51578733, COSV51579816; called by muse, mutect2, varscan2
- TG | c.7156C>T p.R2386C | Missense Mutation (SNP) | VAF 19/38 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs772016260, COSV55096004; called by muse, mutect2, varscan2
- TLR4 | c.812A>C p.K271T (on ENST00000355622 / NM_138554.5; = p.K231T on NM_003266.4) | Missense Mutation (SNP) | VAF 167/235 reads (71%) | SIFT tolerated (0.43); PolyPhen benign (0.006); catalogued as COSV62922740; called by muse, mutect2, varscan2
- TMEM108 | c.716C>T p.T239I | Missense Mutation (SNP) | VAF 23/67 reads (34%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.372); catalogued as COSV58866803; called by muse, mutect2, varscan2
- TMEM95 | c.61C>T p.R21C | Missense Mutation (SNP) | VAF 20/40 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.007); catalogued as rs780917440, COSV50134482; called by muse, mutect2, varscan2
- TMPRSS11F | c.143T>G p.V48G | Missense Mutation (SNP) | VAF 54/137 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV62465565; called by muse, mutect2, varscan2
- TPO | c.1477G>A p.G493S | Missense Mutation (SNP) | VAF 58/85 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs778515113, CM022475, COSV61094451; called by muse, mutect2, varscan2
- TRPC3 | c.418G>A p.V140I (on ENST00000379645 / NM_001366479.2; = p.V67I on NM_003305.2) | Missense Mutation (SNP) | VAF 34/97 reads (35%) | SIFT tolerated (0.38); PolyPhen benign (0.358); catalogued as rs770588520, COSV53373314; called by muse, mutect2, varscan2
- UHRF2 | c.695G>A p.R232Q | Missense Mutation (SNP) | VAF 61/125 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52791636; called by muse, mutect2, varscan2
- VEGFC | c.1124A>G p.K375R | Missense Mutation (SNP) | VAF 167/409 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV54595593, COSV54604452; called by muse, varscan2
- YTHDC1 | c.1106C>G p.S369C (on ENST00000344157 / NM_001031732.4; = p.S351C on NM_133370.4) | Missense Mutation (SNP) | VAF 59/156 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV60009348; called by muse, mutect2, varscan2
- ZMAT3 | c.145G>A p.G49R | Missense Mutation (SNP) | VAF 133/200 reads (67%) | SIFT tolerated (0.82); PolyPhen benign (0.001); catalogued as rs1460705234, COSV60992537, COSV60994346; called by muse, mutect2, varscan2
- ZNF790 | c.97G>A p.V33M | Missense Mutation (SNP) | VAF 17/135 reads (13%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.579); catalogued as COSV63212165; called by muse, mutect2, varscan2
- ZNF804B | c.2737T>G p.S913A | Missense Mutation (SNP) | VAF 65/258 reads (25%) | SIFT tolerated (0.69); PolyPhen benign (0.01); catalogued as COSV60821237; called by muse, mutect2, varscan2
- ARHGAP27 | c.1346del p.P449Lfs*44 (on ENST00000428638 / NM_001282290.1; = p.P108Lfs*44 on NM_199282.3) | Frame Shift Del (DEL) | VAF 15/115 reads (13%) | called by mutect2, pindel, varscan2
- OR1L4 | c.189dup p.L64Sfs*18 | Frame Shift Ins (INS) | VAF 52/153 reads (34%) | called by mutect2, varscan2
- PCDHGA10 | c.256_261del p.G86_S87del | In Frame Del (DEL) | VAF 20/105 reads (19%) | called by mutect2, pindel, varscan2
- PCDHGA4 | c.1255G>A p.D419N | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.041); called by muse, mutect2
- PELI3 | c.762del p.V255Sfs*61 | Frame Shift Del (DEL) | VAF 45/129 reads (35%) | called by mutect2, pindel, varscan2
- APOB | c.10569C>G p.S3523= | Silent (SNP) | VAF 71/308 reads (23%) | catalogued as COSV51928829; called by muse, varscan2
- C18orf25 | c.1146T>C p.T382= | Silent (SNP) | VAF 47/67 reads (70%) | catalogued as COSV56365683; called by muse, mutect2, varscan2
- CSMD1 | c.9468C>T p.C3156= (on ENST00000520002; = p.C3155= on NM_033225.6) | Silent (SNP) | VAF 13/33 reads (39%) | catalogued as rs767013119, COSV104408952, COSV59299053; called by muse, mutect2, varscan2
- CSMD1 | c.2781C>T p.C927= (on ENST00000520002; = p.C926= on NM_033225.6) | Silent (SNP) | VAF 3/11 reads (27%) | catalogued as rs1322382318, COSV59299069; called by muse, mutect2
- DCC | c.1590A>G p.P530= | Silent (SNP) | VAF 114/212 reads (54%) | catalogued as rs1325991983, COSV59092424; called by muse, mutect2, varscan2
- DCLK1 | c.204C>T p.Y68= | Silent (SNP) | VAF 22/196 reads (11%) | catalogued as rs201694528; called by muse, mutect2, varscan2
- DDIT4L | c.399T>G p.T133= | Silent (SNP) | VAF 28/141 reads (20%) | catalogued as rs1232473397, COSV56767094; called by muse, mutect2, varscan2
- DLGAP5 | c.222G>A p.K74= | Silent (SNP) | VAF 65/142 reads (46%) | catalogued as COSV55962575; called by muse, mutect2, varscan2
- EXOC2 | c.1785G>A p.A595= | Silent (SNP) | VAF 9/52 reads (17%) | catalogued as rs761044569, COSV57862797; called by muse, mutect2, varscan2
- FAT3 | c.1176T>C p.G392= | Silent (SNP) | VAF 23/36 reads (64%) | catalogued as COSV53090403; called by muse, mutect2, varscan2
- FOXN3 | c.237G>A p.S79= | Silent (SNP) | VAF 36/150 reads (24%) | catalogued as rs764906969, COSV54305991; called by muse, mutect2, varscan2
- GALNT12 | c.576G>A p.S192= | Silent (SNP) | VAF 6/13 reads (46%) | catalogued as rs780652927, COSV66662337; called by muse, mutect2, varscan2
- KDM4D | c.633T>C p.T211= | Silent (SNP) | VAF 74/109 reads (68%) | catalogued as COSV58634067, COSV58635953; called by muse, mutect2, varscan2
- KRT74 | c.867C>T p.H289= | Silent (SNP) | VAF 10/68 reads (15%) | catalogued as rs371350159; called by muse, mutect2, varscan2
- LRRC59 | c.615C>T p.A205= | Silent (SNP) | VAF 68/358 reads (19%) | catalogued as COSV56814046; called by muse, mutect2, varscan2
- MLPH | c.1419C>G p.A473= | Silent (SNP) | VAF 16/21 reads (76%) | catalogued as COSV52819102; called by muse, varscan2
- NCAN | c.3360C>T p.S1120= | Silent (SNP) | VAF 40/65 reads (62%) | catalogued as rs146079504; called by muse, mutect2, varscan2
- NEK10 | c.2625C>T p.D875= | Silent (SNP) | VAF 83/253 reads (33%) | catalogued as rs547219395, COSV55356576; called by muse, mutect2, varscan2
- NOL4 | c.1203C>T p.D401= | Silent (SNP) | VAF 39/165 reads (24%) | catalogued as rs141277558; called by muse, mutect2, varscan2
- PCDHA6 | c.2055C>T p.G685= | Silent (SNP) | VAF 17/69 reads (25%) | catalogued as COSV65342972; called by muse, mutect2, varscan2
- PGAP3 | c.828G>A p.P276= | Silent (SNP) | VAF 12/24 reads (50%) | catalogued as rs375997053; called by muse, mutect2, varscan2
- PREX2 | c.4431C>T p.N1477= | Silent (SNP) | VAF 22/38 reads (58%) | catalogued as rs137974526, COSV55778411; called by muse, mutect2, varscan2
- SDC2 | c.372C>T p.A124= | Silent (SNP) | VAF 67/102 reads (66%) | catalogued as rs766386558, COSV56225722; called by muse, mutect2, varscan2
- SLC29A1 | c.393G>A p.K131= | Silent (SNP) | VAF 21/59 reads (36%) | catalogued as COSV57577693; called by muse, mutect2, varscan2
- SYNE1 | c.8169C>T p.H2723= (on ENST00000367255 / NM_182961.4; = p.H2730= on NM_033071.3) | Silent (SNP) | VAF 30/143 reads (21%) | catalogued as rs371449580; called by muse, mutect2, varscan2
- UNC79 | c.4887C>T p.S1629= (on ENST00000393151 / NM_001346218.2; = p.S1452= on NM_020818.5) | Silent (SNP) | VAF 43/182 reads (24%) | catalogued as rs781387821, COSV56377182; called by muse, mutect2, varscan2
- ZFHX4 | c.6006G>A p.T2002= | Silent (SNP) | VAF 86/120 reads (72%) | catalogued as rs1336045561, COSV50639746; called by muse, mutect2, varscan2
- ZNF710 | c.1702C>T p.L568= | Silent (SNP) | VAF 38/93 reads (41%) | catalogued as COSV51562142; called by muse, mutect2, varscan2
- ZNF768 | c.1380C>T p.P460= | Silent (SNP) | VAF 10/30 reads (33%) | catalogued as rs763981973, COSV63320920; called by muse, mutect2, varscan2
- FOLH1B | n.2036A>C | RNA (SNP) | VAF 45/192 reads (23%) | called by muse, mutect2, varscan2
